Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00Q, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00Q-01A (Primary Tumor).

ICD-0-3
adenocarcinoma, nos 8140/3
Site: sigmoid colon C18.7 w 3/29/11

Sample ID #:

Diagnosis:

- 1.: Normal, tumor-free gall bladder with no macroscopic or microscopic indications of the presence of a polyp and with no notable florid or chronic inflammatory changes. Two tumor-free perivesicular lymph nodes.
- 2.: A further tumor-free lymph node.
- 3.: Resectate of the colon (sigmoid colon) with tumor-free oral and aboral resection margins and under inclusion of an ulcerated, moderately differentiated adenocarcinoma with penetration of all layers of the wall, penetration of the peritoneum, encroaching on the subserosa of a segment of the small intestine in the vicinity and with a solitary regional lymph node metastasis (G2, pT4 L1 V0 pN1 1/31).

Source: NCI Genomic Data Commons file 20bc24e3-dac1-4fb5-8e69-18041d320026 (TCGA-AA-A00Q.7F67E829-D10E-4B47-B0A1-6029B57ED112.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).